Somatic mutation profile of tumor specimen C3N-02285-03 (aliquot CPT0126740006) from CPTAC case C3N-02285, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 72.8 years (26,573 days).
Specimen C3N-02285-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfd3c156-2cbb-46e8-838e-d3654bbc10bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02285-31 (Blood Derived Normal), aliquot CPT0126800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dcd44ca-88b0-4554-8188-2d1f26ef30ad

The open-access MAF lists 394 somatic variants for this specimen: 272 protein-altering or splice-affecting, 70 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 239, Silent 70, Intron 26, Nonsense Mutation 16, RNA 11, Frame Shift Del 7, 5'UTR 5, 3'UTR 5, Splice Region 4, Splice Site 4, 5'Flank 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264102348, COSV60685214; called by muse, mutect2
- ADCY10 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63238501; called by muse, mutect2
- ADGRG2 | c.2863G>A p.G955R (on ENST00000379869 / NM_001079858.3; = p.G952R on NM_005756.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs749784528, COSV61340723; called by muse, mutect2, varscan2
- AMER2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs763913776; called by muse, varscan2
- ANKRD11 | c.6587C>T p.S2196F | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV56361230; called by muse, mutect2, varscan2
- ANKRD45 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100322543, COSV60960882; called by muse, mutect2
- ARHGAP33 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); catalogued as rs560613610; called by mutect2, varscan2
- ARMCX6 | c.195G>C p.M65I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1556035895; called by muse, mutect2, varscan2
- ASPM | c.6254A>G p.H2085R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs777722614; called by muse, mutect2, varscan2
- ATP2B3 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 34/268 reads (13%) | catalogued as COSV54843028; called by muse, varscan2
- BIVM-ERCC5 | c.4898C>G p.A1633G | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated, low confidence (0.39); catalogued as rs998046185, COSV63245748; called by muse, mutect2, varscan2
- BPIFB4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs373461211; called by muse, mutect2, varscan2
- BTK | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs930891306, COSV58118079, COSV58122495; called by muse, mutect2, varscan2
- CEBPA | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV57197001, COSV57199791; called by muse, varscan2
- CNTNAP4 | c.3668C>T p.S1223F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.976); catalogued as rs776078327; called by muse, mutect2, varscan2
- COG2 | c.1555G>C p.D519H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794599; called by muse, mutect2, varscan2
- CPT1A | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 108/530 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs759848299; called by muse, mutect2, varscan2
- CREBBP | c.6519C>G p.I2173M | Missense Mutation (SNP) | VAF 98/658 reads (15%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs572471926; called by muse, varscan2
- CTNNA2 | c.820G>C p.G274R | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100786127, COSV63548356; called by muse, varscan2
- CUX1 | c.1074G>A p.L358= (on ENST00000292535 / NM_181552.4; = p.L369= on NM_001913.5) | Splice Region (SNP) | VAF 26/186 reads (14%) | catalogued as rs1554516489; called by muse, mutect2, varscan2
- DDX42 | c.2554C>G p.R852G | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.071); catalogued as rs772723138, COSV100834817, COSV100834846; called by muse, mutect2, varscan2
- DNAJC5G | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs1217651583; called by muse, mutect2
- DPYSL3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1293421134; called by muse, mutect2
- DST | c.16057G>C p.A5353P (on ENST00000361203 / NM_001374722.1; = p.A2941P on NM_015548.5) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs923665801; called by muse, mutect2
- EBF3 | c.950C>T p.P317L (on ENST00000355311 / NM_001375392.1; = p.P308L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as rs759238126; called by muse, mutect2, varscan2
- ELF1 | c.277del p.D93Mfs*28 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | catalogued as COSV53501464; called by mutect2, pindel, varscan2
- ENAM | c.1285C>G p.R429G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1343700582, COSV68535280; called by muse, mutect2, varscan2
- EPHA7 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV100992372; called by muse, mutect2, varscan2
- FAM135B | c.3529G>C p.E1177Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52756414; called by muse, mutect2
- FAT3 | c.13448G>A p.S4483N | Missense Mutation (SNP) | VAF 81/475 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1297391762; called by muse, mutect2, varscan2
- FBXL20 | c.976C>G p.R326G | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV52897487; called by muse, mutect2
- FCRLA | c.193G>A p.E65K (on ENST00000367959; = p.E42K on NM_032738.4) | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV52685545; called by muse, mutect2, varscan2
- FGF22 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1427204057; called by muse, mutect2, varscan2
- FUT4 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2
- GCC1 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV58462300, COSV58462572; called by muse, mutect2
- GGH | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52650002; called by muse, mutect2, varscan2
- GPR141 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as COSV57732962; called by muse, mutect2, varscan2
- GPRIN3 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs759137007; called by muse, mutect2, varscan2
- H2AC20 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 99/640 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782250000; called by muse, mutect2, varscan2
- HMCN1 | c.14425G>A p.D4809N | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as rs1436027422; called by muse, mutect2
- KLHL6 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 59/548 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs532480044; called by muse, mutect2, varscan2
- KRT74 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs747946851, COSV59770370; called by muse, mutect2, varscan2
- KRT83 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 101/593 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs766187594, COSV53341542; called by muse, mutect2, varscan2
- LARGE1 | c.2264_2266del p.N755del | In Frame Del (DEL) | VAF 50/395 reads (13%) | catalogued as rs749216721; called by pindel, varscan2
- LRFN5 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV53254710; called by muse, mutect2, varscan2
- MED12 | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100379663, COSV61352274; called by muse, mutect2
- MPC1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1233467255; called by muse, mutect2, varscan2
- NSG2 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV57458085; called by muse, mutect2, varscan2
- NTN1 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.364); catalogued as rs1401636588; called by muse, mutect2
- OAT | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157058376; called by muse, mutect2, varscan2
- OR2L3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs755534000, COSV63456299; called by muse, varscan2
- OR5D16 | c.457T>C p.W153R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs950218176; called by muse, mutect2, varscan2
- OR5H14 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1184502493, COSV101454256, COSV71193845; called by muse, varscan2
- OR5T3 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs368667732; called by muse, mutect2
- PAFAH2 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.659); catalogued as rs768839456; called by muse, mutect2, varscan2
- PCDHGC4 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1371072899, COSV52756803, COSV52776879; called by muse, mutect2
- PDZD2 | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56862329; called by muse, mutect2
- PLA2G4A | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV66553241; called by muse, mutect2, varscan2
- POTED | c.1475A>G p.E492G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100203035; called by muse, mutect2, varscan2
- PRAMEF12 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV63215607, COSV99080813; called by muse, mutect2
- PRDM9 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 197/423 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs758131778; called by muse, mutect2, varscan2
- PRPF40B | c.393G>C p.E131D (on ENST00000380281; = p.E125D on NM_012272.3) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56061755; called by muse, mutect2, varscan2
- RASSF10 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as rs778131389; called by muse, mutect2, varscan2
- RFC5 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 66/500 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201152888; called by muse, mutect2, varscan2
- RP1L1 | c.6817C>T p.P2273S | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV66754851; called by muse, mutect2, varscan2
- RYR1 | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs754426488; called by muse, mutect2, varscan2
- SCAMP3 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as COSV100226753; called by muse, mutect2, varscan2
- SELENOP | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as rs759244077, COSV72484671; called by mutect2, varscan2
- SLC12A1 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs751250413, COSV66791811; called by muse, mutect2
- SLC18A3 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV60327996; called by muse, mutect2, varscan2
- SLC24A5 | c.489G>C p.T163= | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as COSV58317496; called by muse, mutect2, varscan2
- SLC25A14 | c.701C>A p.T234K | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.643); catalogued as rs372335758; called by muse, mutect2, varscan2
- SLC25A28 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65125433; called by muse, mutect2, varscan2
- SLC41A3 | c.517C>G p.R173G | Missense Mutation (SNP) | VAF 30/593 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs11543282; called by muse, mutect2
- SNRPN | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.292); catalogued as COSV57593762; called by muse, mutect2, varscan2
- SOGA1 | c.4439G>C p.R1480P | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52922789; called by muse, mutect2, varscan2
- SPATA18 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54646493; called by muse, mutect2, varscan2
- SRPX | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs764536488, COSV100656100; called by muse, varscan2
- STAG2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99493739; called by muse, mutect2, varscan2
- STARD8 | c.2376C>A p.S792R | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV52934053; called by muse, mutect2, varscan2
- STMN4 | c.132G>A p.W44* (on ENST00000265770 / NM_001283054.2; = p.W71* on NM_030795.4) | Nonsense Mutation (SNP) | VAF 31/179 reads (17%) | catalogued as COSV99740602; called by muse, mutect2, varscan2
- STRA8 | c.932C>T p.P311L (on ENST00000275764; = p.P289L on NM_182489.2) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV51962655; called by muse, mutect2, varscan2
- TEX13A | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV61172451; called by muse, mutect2, varscan2
- THSD7B | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 18/242 reads (7%) | catalogued as COSV55667446; called by muse, mutect2
- TMEM200A | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as rs1353729504, COSV51657998; called by muse, mutect2, varscan2
- TNN | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as COSV53425332; called by muse, mutect2, varscan2
- TP53 | c.250del p.A84Pfs*39 | Frame Shift Del (DEL) | VAF 37/248 reads (15%) | catalogued as COSV53077353; called by mutect2, pindel, varscan2
- TRDN | c.2149G>T p.G717C | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs368860243, COSV62123938; called by muse, mutect2, varscan2
- TRPC3 | c.518C>G p.A173G (on ENST00000379645 / NM_001366479.2; = p.A100G on NM_003305.2) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53378851; called by muse, mutect2, varscan2
- TUBB2B | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 70/500 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99455428; called by muse, varscan2
- TXNRD2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs994880290, COSV100538584; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV54438441; called by muse, mutect2, varscan2
- UNC93A | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV57810939; called by muse, mutect2, varscan2
- VPS13B | c.6709G>A p.D2237N | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV62139938; called by muse, mutect2, varscan2
- ZNF254 | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1403748852, COSV61645128; called by muse, mutect2, varscan2
- ABCD1 | c.2201C>A p.P734Q | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAA2 | c.788C>A p.A263D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ADRA2A | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- AFF4 | c.2571_2572del p.N857Kfs*17 | Frame Shift Del (DEL) | VAF 74/347 reads (21%) | called by mutect2, pindel, varscan2
- ALAS2 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- APBB2 | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APC2 | c.6026C>G p.S2009C | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ARHGAP22 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP4 | c.1923-1G>T p.X641_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | called by muse, varscan2
- ARSA | c.783del p.T262Pfs*2 | Frame Shift Del (DEL) | VAF 55/362 reads (15%) | called by mutect2, pindel, varscan2
- ATXN2L | c.2485A>T p.S829C | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- BCOR | c.78C>A p.S26R | Missense Mutation (SNP) | VAF 70/484 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C10orf67 | c.1571-1G>C p.X524_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
- C11orf80 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- C2CD2L | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CADM1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- CAPSL | c.108G>T p.R36S | Missense Mutation (SNP) | VAF 211/429 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC136 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- CCDC22 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CCDC93 | c.782C>A p.T261N | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, varscan2
- CCN2 | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD300LG | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CDK5RAP1 | c.1189C>G p.Q397E (on ENST00000357886 / NM_001365728.1; = p.Q383E on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- CDX1 | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CEP89 | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHD2 | c.4268A>G p.K1423R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- CLASP2 | c.3959A>G p.H1320R (on ENST00000359576; = p.H1319R on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CLDN18 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNDP2 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- CNTLN | c.3435G>T p.M1145I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- COL11A2 | c.3047C>T p.S1016F (on ENST00000341947 / NM_080680.3; = p.S909F on NM_080679.2) | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL6A5 | c.4862G>A p.G1621E | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- CRB1 | c.2534G>T p.G845V | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- CREB3L2 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- CSTF1 | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 71/515 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CYBB | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4B1 | c.1483A>T p.K495* | Nonsense Mutation (SNP) | VAF 56/324 reads (17%) | called by muse, mutect2, varscan2
- DNAH8 | c.13454T>C p.L4485P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAI2 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 97/537 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DOCK11 | c.3737C>A p.A1246E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DPPA4 | c.402C>G p.S134R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.223); called by muse, mutect2
- DPYD | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DRD2 | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP10 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DVL3 | c.762G>T p.M254I | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- EDA | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- EFCAB5 | c.279del p.K93Nfs*5 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- EPHA10 | c.2182C>A p.H728N | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- EVC2 | c.1729A>T p.M577L | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- F8 | c.3862T>A p.S1288T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FAM13A | c.1904T>A p.V635E | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- FAM171A2 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.672); called by mutect2, varscan2
- FAM47A | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FAM71E2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- FAT4 | c.4744G>T p.G1582* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- FILIP1L | c.2244A>T p.K748N (on ENST00000354552 / NM_182909.3; = p.K508N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.8120C>A p.S2707Y | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNA13 | c.337A>T p.N113Y | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GOLM1 | c.585C>A p.D195E | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPAT2 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- GPIHBP1 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GRM3 | c.579dup p.D194Rfs*10 | Frame Shift Ins (INS) | VAF 76/386 reads (20%) | called by mutect2, pindel, varscan2
- GRM4 | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- HBE1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 60/349 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDX | c.527T>C p.L176S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- HEXD | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- HLX | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HNRNPUL1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- INSRR | c.3130C>A p.R1044S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA4 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR1 | c.2337G>T p.R779S (on ENST00000354582; = p.R764S on NM_002222.7) | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KCNC2 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNT1 | c.2138del p.S713Wfs*5 (on ENST00000488444; = p.S732Wfs*5 on NM_020822.3) | Frame Shift Del (DEL) | VAF 29/171 reads (17%) | called by mutect2, pindel, varscan2
- KCNV2 | c.1537A>T p.R513W | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- KIF19 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF4B | c.1103C>A p.A368D | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- KMT2D | c.14382+1G>T p.X4794_splice | Splice Site (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- KNDC1 | c.1731C>G p.I577M | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- KPRP | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- LAMC1 | c.2896G>T p.E966* | Nonsense Mutation (SNP) | VAF 41/323 reads (13%) | called by muse, mutect2, varscan2
- LARP6 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- LCMT2 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- LSG1 | c.1888G>C p.E630Q | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2
- LYG2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2
- MAGEE2 | c.241del p.A81Rfs*8 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- MAS1 | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- MASTL | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- MED12 | c.5757G>T p.Q1919H | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MFSD9 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 33/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MKNK2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2
- MRC2 | c.3202C>G p.P1068A | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MTUS2 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYCBPAP | c.1419G>C p.M473I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MYH2 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MYOM1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- NBPF12 | c.3418G>T p.A1140S | Missense Mutation (SNP) | VAF 92/550 reads (17%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- NCAM2 | c.1318G>T p.V440F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIPBL | c.5878G>C p.E1960Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- NOX1 | c.639C>G p.F213L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- NR0B1 | c.482C>G p.A161G | Missense Mutation (SNP) | VAF 107/676 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- OR52B2 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2
- OR52N4 | c.637A>T p.I213L | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ORAI3 | c.818A>C p.H273P | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL8 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- PABPC4 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PACRG | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PASD1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PCSK1N | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PIMREG | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 102/404 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.1348-4C>T | Splice Region (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PITX2 | c.206G>T p.G69V (on ENST00000354925 / NM_001204397.1; = p.G76V on NM_000325.6) | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PKHD1 | c.7436T>A p.L2479H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PLD5 | c.1465G>A p.V489M (on ENST00000442594; = p.V427M on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PPFIA4 | c.3398G>A p.R1133H (on ENST00000447715; = p.R1134H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIB | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 80/492 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R2C | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PPP6R1 | c.1234A>T p.S412C | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PREX2 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- PRKCA | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 45/263 reads (17%) | called by muse, mutect2, varscan2
- PRKCG | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 130/836 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by mutect2, varscan2
- RAB3GAP1 | c.2863C>G p.L955V | Missense Mutation (SNP) | VAF 96/600 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RASSF3 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RBBP8NL | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RBM10 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 58/427 reads (14%) | called by muse, mutect2, varscan2
- REPIN1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- REPS2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RIPK2 | c.1123+1G>T p.X375_splice | Splice Site (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- RLIM | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RNF10 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- RTKN | c.1237C>T p.Q413* (on ENST00000272430 / NM_001015055.2; = p.Q400* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- RTL5 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- RYR2 | c.3010C>T p.H1004Y | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SALL3 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 80/427 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- SART1 | c.2220G>C p.K740N | Missense Mutation (SNP) | VAF 63/450 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCX | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SLA | c.290T>C p.L97P (on ENST00000338087 / NM_001045556.3; = p.L137P on NM_006748.4) | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC15A2 | c.1537G>T p.G513W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC25A43 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC26A3 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2
- SLC2A11 | c.730G>C p.E244Q (on ENST00000345044 / NM_001024938.4; = p.E251Q on NM_030807.5) | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2
- SLC38A5 | c.1196A>C p.D399A | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC41A2 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC5A8 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMARCA1 | c.2291G>T p.R764I | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SMC5 | c.2420A>G p.E807G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2
- SP110 | c.469A>C p.S157R | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG17 | c.5894C>T p.S1965L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SREBF2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SRPK1 | c.511C>G p.H171D | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); called by muse, mutect2
- SRPK3 | c.1139C>G p.S380W | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STAB2 | c.7003T>A p.S2335T | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- STXBP5 | c.1929G>T p.L643= | Splice Region (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- TCERG1 | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TEF | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 92/521 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TENT4A | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 158/348 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM185A | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 39/488 reads (8%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.471); called by muse, mutect2
- TNRC6A | c.1895G>C p.G632A | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TRGJP2 | c.46A>T p.I16L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- TTLL4 | c.3265C>G p.L1089V | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, varscan2
- TTN | c.97300C>A p.Q32434K (on ENST00000591111; = p.Q25010K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/258 reads (15%) | PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TTN | c.38996G>T p.R12999L (on ENST00000591111; = p.R5575L on NM_003319.4) | Missense Mutation (SNP) | VAF 52/264 reads (20%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ULK4 | c.1237A>T p.I413F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- USP9X | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- VAMP2 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR44 | c.2104C>G p.Q702E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZC3H8 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2
- ZDHHC5 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZFYVE9 | c.3393A>T p.E1131D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF275 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ZNF41 | c.1238G>T p.C413F | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF649 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNF804B | c.3517C>A p.L1173I | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZSCAN10 | c.49T>A p.W17R (on ENST00000252463; = p.W72R on NM_032805.3) | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AICDA | c.534C>T p.R178= | Silent (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- CACNG7 | c.324C>T p.L108= | Silent (SNP) | VAF 56/309 reads (18%) | catalogued as COSV99712020; called by muse, mutect2, varscan2
- CAMTA1 | c.4380T>C p.Y1460= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs958292170; called by muse, mutect2
- CCDC124 | c.9G>A p.K3= | Silent (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- CCPG1 | c.51C>T p.I17= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- CLCN6 | c.2394C>T p.R798= | Silent (SNP) | VAF 41/249 reads (16%) | called by muse, mutect2, varscan2
- COL4A5 | c.4545C>A p.T1515= | Silent (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- CYB561D1 | c.322C>T p.L108= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV60205899; called by muse, mutect2, varscan2
- DOC2B | c.540C>A p.L180= | Silent (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- EFS | c.1245G>T p.A415= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV53732056; called by muse, mutect2, varscan2
- EGLN3 | c.588C>T p.H196= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs370813407, COSV51655945; called by muse, varscan2
- EPAS1 | c.471A>G p.K157= | Silent (SNP) | VAF 86/480 reads (18%) | called by muse, mutect2, varscan2
- EPHA6 | c.1806C>G p.A602= | Silent (SNP) | VAF 64/253 reads (25%) | called by muse, mutect2, varscan2
- FAM171B | c.1749G>T p.T583= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV59002846; called by muse, mutect2, varscan2
- FCRL3 | c.1246C>A p.R416= | Silent (SNP) | VAF 26/242 reads (11%) | catalogued as COSV63840328; called by muse, mutect2, varscan2
- GABRA5 | c.339G>T p.G113= | Silent (SNP) | VAF 66/505 reads (13%) | called by muse, mutect2, varscan2
- GPR143 | c.195G>A p.P65= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs1478859621; called by muse, mutect2, varscan2
- GPR158 | c.774G>T p.G258= | Silent (SNP) | VAF 57/397 reads (14%) | catalogued as COSV66267475; called by muse, mutect2, varscan2
- ID1 | c.285C>G p.L95= | Silent (SNP) | VAF 15/412 reads (4%) | catalogued as rs948921953; called by muse, mutect2
- IDS | c.237G>T p.A79= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as COSV61711047, COSV61712603; called by muse, mutect2, varscan2
- IRX6 | c.483C>T p.L161= | Silent (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- ITGA8 | c.885T>C p.F295= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, varscan2
- ITIH5 | c.141C>A p.T47= | Silent (SNP) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- KIAA2013 | c.375C>T p.F125= | Silent (SNP) | VAF 38/603 reads (6%) | called by muse, mutect2
- MBD4 | c.27G>T p.L9= | Silent (SNP) | VAF 263/666 reads (39%) | catalogued as COSV99959754; called by muse, mutect2, varscan2
- ME2 | c.1131T>C p.F377= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- MUC17 | c.4947C>T p.S1649= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- MYO1C | c.2943A>G p.V981= (on ENST00000648651 / NM_001080779.2; = p.V946= on NM_033375.5) | Silent (SNP) | VAF 107/431 reads (25%) | called by muse, mutect2, varscan2
- NFATC3 | c.1167T>C p.G389= | Silent (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- NOP9 | c.1035G>A p.Q345= | Silent (SNP) | VAF 24/235 reads (10%) | called by muse, mutect2, varscan2
- NSDHL | c.900C>A p.A300= | Silent (SNP) | VAF 36/200 reads (18%) | called by muse, mutect2, varscan2
- NSG2 | c.234G>T p.L78= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV100292856; called by muse, mutect2, varscan2
- NT5C3B | c.663C>T p.G221= | Silent (SNP) | VAF 70/392 reads (18%) | called by muse, mutect2, varscan2
- OR10Q1 | c.399G>C p.P133= | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as COSV57469977; called by muse, mutect2, varscan2
- OR6K6 | c.363C>T p.S121= (on ENST00000368144; = p.S97= on NM_001005184.1) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs769249699, COSV63744847; called by muse, mutect2, varscan2
- OTOP1 | c.51C>A p.A17= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- PAX2 | c.1086G>T p.V362= (on ENST00000428433 / NM_003987.5; = p.V339= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV62292779; called by muse, mutect2, varscan2
- PCSK6 | c.2805C>T p.C935= | Silent (SNP) | VAF 36/261 reads (14%) | called by muse, mutect2, varscan2
- PDGFC | c.285G>T p.G95= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- PDZD7 | c.162C>G p.P54= | Silent (SNP) | VAF 54/388 reads (14%) | called by mutect2, varscan2
- PLCL1 | c.630G>T p.V210= | Silent (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- POFUT2 | c.762G>A p.R254= | Silent (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.486C>T p.L162= | Silent (SNP) | VAF 21/297 reads (7%) | catalogued as rs375126363; called by muse, mutect2
- PTPN12 | c.1752T>C p.H584= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- RGS4 | c.513T>A p.S171= | Silent (SNP) | VAF 72/489 reads (15%) | called by muse, mutect2, varscan2
- ROBO2 | c.924C>G p.L308= | Silent (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- SCX | c.27G>A p.A9= | Silent (SNP) | VAF 38/238 reads (16%) | catalogued as rs1163564636; called by muse, mutect2, varscan2
- SPARCL1 | c.306C>T p.D102= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs1294148988; called by muse, mutect2
- SPTA1 | c.6520C>T p.L2174= | Silent (SNP) | VAF 44/341 reads (13%) | catalogued as COSV63756351; called by muse, mutect2, varscan2
- SUPT5H | c.1863C>T p.F621= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as rs748543064, COSV100782070; called by muse, mutect2
- SYNE1 | c.15837C>G p.L5279= (on ENST00000367255 / NM_182961.4; = p.L5208= on NM_033071.3) | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as COSV54975573; called by muse, mutect2
- TAS1R2 | c.1968C>G p.V656= | Silent (SNP) | VAF 137/924 reads (15%) | called by muse, mutect2, varscan2
- TBX19 | c.1215G>T p.V405= | Silent (SNP) | VAF 87/514 reads (17%) | called by muse, mutect2, varscan2
- TET3 | c.336G>T p.P112= | Silent (SNP) | VAF 41/298 reads (14%) | called by muse, mutect2, varscan2
- TEX13C | c.2757T>C p.G919= | Silent (SNP) | VAF 48/220 reads (22%) | called by muse, mutect2, varscan2
- TG | c.8028G>A p.R2676= | Silent (SNP) | VAF 67/388 reads (17%) | called by muse, mutect2, varscan2
- TLL2 | c.1323C>T p.L441= | Silent (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- TMEM147 | c.243G>C p.L81= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV52866063, COSV52870579, COSV99382657; called by muse, mutect2
- TMEM151B | c.840C>T p.F280= | Silent (SNP) | VAF 42/334 reads (13%) | catalogued as rs1409762624, COSV65256030; called by muse, mutect2, varscan2
- TNFRSF11A | c.1137G>A p.E379= | Silent (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.2580G>T p.L860= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- TRIM49C | c.66C>T p.F22= | Silent (SNP) | VAF 17/78 reads (22%) | called by mutect2, varscan2
- TTN | c.65382G>T p.T21794= (on ENST00000591111; = p.T14370= on NM_003319.4) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs397517684; called by mutect2, varscan2
- VPS52 | c.1890A>C p.R630= | Silent (SNP) | VAF 57/285 reads (20%) | called by muse, mutect2, varscan2
- VTA1 | c.246A>G p.Q82= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- WDFY4 | c.3747G>A p.L1249= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- ZC3H18 | c.1158G>A p.E386= | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- ZNF268 | c.2370C>T p.S790= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as rs1469179718; called by muse, mutect2
- ZNF284 | c.1341G>A p.R447= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs376081140; called by muse, mutect2, varscan2
- ZNF516 | c.519G>T p.A173= | Silent (SNP) | VAF 55/324 reads (17%) | catalogued as rs767596915, COSV71587698; called by muse, mutect2, varscan2
- AC007342.3 | n.267del | RNA (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel, varscan2
- AC009533.1 | n.725A>G | RNA (SNP) | VAF 111/867 reads (13%) | catalogued as rs1429811191; called by muse, mutect2, varscan2
- AC016582.1 | chr19:37825087 C>T | 3'Flank (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- ACSL4 | c.-479C>A | 5'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- AL353804.4 | chrX:73821525 G>A | 3'Flank (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ARHGEF4 | chr2:130915220 G>T | 5'Flank (SNP) | VAF 41/267 reads (15%) | called by muse, mutect2, varscan2
- ATG12 | c.163+52A>T | Intron (SNP) | VAF 67/334 reads (20%) | called by muse, mutect2, varscan2
- ATG12 | c.163+51G>T | Intron (SNP) | VAF 66/334 reads (20%) | called by muse, mutect2, varscan2
- ATP1A3 | c.-46G>C | 5'UTR (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- C5orf17 | n.248C>T | RNA (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- CDK16 | c.*596C>T | 3'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- CDKL5 | c.2713+105C>T | Intron (SNP) | VAF 22/163 reads (13%) | called by muse, mutect2, varscan2
- DSC2 | c.2509-132G>A | Intron (SNP) | VAF 15/106 reads (14%) | catalogued as COSV99199661; called by muse, mutect2, varscan2
- DYNC1I2 | c.245-25G>C | Intron (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
- FAM135B | c.77+536C>A | Intron (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- FCHO1 | c.-68C>T | 5'UTR (SNP) | VAF 23/140 reads (16%) | catalogued as COSV53182219; called by muse, mutect2, varscan2
- FLNA | c.6023-15A>G | Intron (SNP) | VAF 92/548 reads (17%) | called by muse, mutect2, varscan2
- FOLH1B | n.1350G>C | RNA (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- FOXE1 | c.-20G>T | 5'UTR (SNP) | VAF 5/31 reads (16%) | catalogued as COSV64300124; called by muse, mutect2
- GALNT14 | c.129+12722C>G | Intron (SNP) | VAF 23/291 reads (8%) | catalogued as COSV61111664; called by muse, mutect2
- GIMAP6 | c.86-193G>T | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
- GNG5P2 | n.29C>A | RNA (SNP) | VAF 44/263 reads (17%) | catalogued as COSV64438533, COSV64438542; called by muse, mutect2, varscan2
- HSP90AA4P | n.2106G>C | RNA (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- IGSF9B | c.64+4625G>T | Intron (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- KIF5A | c.2992+40C>G | Intron (SNP) | VAF 11/270 reads (4%) | catalogued as rs1167222284; called by muse, mutect2
- KLC4 | c.259-15G>A | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- LINC00482 | n.811C>T | RNA (SNP) | VAF 47/265 reads (18%) | catalogued as rs757627673; called by muse, mutect2, varscan2
- MAN2A2 | c.2994+374C>G | Intron (SNP) | VAF 20/361 reads (6%) | catalogued as rs1288552315; called by muse, mutect2
- MIR9-3 | n.15C>G | RNA (SNP) | VAF 24/472 reads (5%) | called by muse, mutect2
- NIN | c.6079-1669A>G | Intron (SNP) | VAF 49/237 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+4971G>T | Intron (SNP) | VAF 37/303 reads (12%) | called by muse, mutect2, varscan2
- OR2M1P | n.627C>G | RNA (SNP) | VAF 100/470 reads (21%) | catalogued as rs987930809; called by muse, varscan2
- PIEZO1 | c.161-857G>A | Intron (SNP) | VAF 37/265 reads (14%) | catalogued as rs1214489150; called by muse, mutect2, varscan2
- PPP1R2P1 | n.428G>T | RNA (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3448G>T | RNA (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2
- RABL6 | c.*3C>T | 3'UTR (SNP) | VAF 26/105 reads (25%) | catalogued as rs762239302; called by muse, mutect2, varscan2
- RARA | c.*16G>A | 3'UTR (SNP) | VAF 59/404 reads (15%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2049G>T | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158768 C>G | 5'Flank (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- RPL10 | c.*108G>A | 3'UTR (SNP) | VAF 21/101 reads (21%) | called by muse, varscan2
- RTN4R | c.22+407G>T | Intron (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- SLC6A8 | c.1495+22G>T | Intron (SNP) | VAF 103/605 reads (17%) | called by muse, mutect2, varscan2
- SNPH | c.-47-33C>T | Intron (SNP) | VAF 9/162 reads (6%) | catalogued as COSV101118662; called by muse, mutect2
- SPATA21 | c.145-813G>C | Intron (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- STIM1 | c.1541+144C>G | Intron (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- TAFA2 | c.-2+86515G>A | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs1172541411; called by muse, mutect2, varscan2
- TH | c.1197+47C>G | Intron (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- TSC2 | c.3814+26C>G | Intron (SNP) | VAF 90/547 reads (16%) | called by muse, mutect2, varscan2
- XIAP | c.*6495G>A | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- ZGRF1 | c.102+1939G>T | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451309 C>T | 5'Flank (SNP) | VAF 65/473 reads (14%) | catalogued as COSV99989284; called by muse, mutect2, varscan2
- ZNF678 | c.-154G>T | 5'UTR (SNP) | VAF 31/341 reads (9%) | called by muse, mutect2
